Gene-level copy-number profile of tumor specimen ALCH-B1RH-TTP1-A from ALCHEMIST case ALCH-B1RH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 82.1 years (29,981 days).
Specimen ALCH-B1RH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cf0de4d5-884d-438d-bf9a-52c6030f18ba.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1RH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,747 have no estimate.
https://portal.gdc.cancer.gov/files/b346b8de-572d-485b-b34a-16caa37468c3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 117; copy number 1: 10,968; copy number 2: 47,120; copy number 3: 473; copy number 4: 159; copy number 5: 12; copy number 6: 14; copy number 7: 8; copy number 8: 3; copy number 20: 2.

Homozygous deletions (total copy number 0; autosomes only): 90 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,479,827–232,536,667, 3 genes: ECEL1, PRSS56, CHRND.
- chr4:681,829–689,271, 1 gene (within-gene range 0–1): SLC49A3.
- chr7:128,830,406–128,910,719, 5 genes (within-gene range 0–2): FLNC, FLNC-AS1, KCP, ATP6V1F, ATP6V1FNB.
- chr7:151,057,210–151,144,436, 6 genes (within-gene range 0–2): SLC4A2, AC010973.3, AC010973.2, FASTK, TMUB1, AGAP3.
- chr9:93,576,584–93,679,587, 2 genes: PHF2, MIR548AU.
- chr9:124,853,417–124,861,981, 2 genes: WDR38, RPL35.
- chr11:46,385,098–46,386,608, 1 gene: CHRM4.
- chr14:73,237,497–73,274,640, 4 genes (within-gene range 0–2): PAPLN, AC004846.1, RNU6-419P, AC004846.2.
- chr14:102,922,663–102,933,596, 1 gene (within-gene range 0–2): AMN.
- chr14:102,933,574–102,937,177, 1 gene (within-gene range 0–2): AL117209.1.
- chr14:103,525,010–103,537,073, 2 genes: AL133367.1, TRMT61A.
- chr15:41,837,775–41,899,528, 5 genes (within-gene range 0–2): PLA2G4B, SPTBN5, RNA5SP393, MIR4310, AC020659.1.
- chr15:85,750,336–85,794,925, 5 genes: AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1.
- chr15:90,954,870–90,963,125, 1 gene (within-gene range 0–1): RCCD1.
- chr16:21,401,089–21,448,567, 2 genes (within-gene range 0–1): AC008740.2, NPIPB3.
- chr16:21,519,830–21,550,373, 4 genes (within-gene range 0–1): SLC7A5P2, AC005632.5, AC005632.2, AC005632.4.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:2,688,473–3,037,741, 10 genes: AC005696.3, CLUH, MIR6776, AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253, RAP1GAP2, AC015921.1.
- chr17:3,565,444–3,636,250, 6 genes: TRPV1, AC027796.5, AC027796.3, AC027796.1, SHPK, AC027796.2.
- chr17:7,351,889–7,357,219, 3 genes: KCTD11, AC026954.3, TMEM95.
- chr17:19,719,059–19,722,428, 1 gene: AC005722.3.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–1): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:15,114,984–15,126,174, 2 genes (within-gene range 0–1): ILVBL, AC003956.1.
- chr19:19,512,418–19,663,676, 11 genes: TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2, PBX4, PHF5CP, AC002306.1, LPAR2, GMIP, ATP13A1.
- chr21:44,172,169–44,194,338, 2 genes: AP001056.2, AP001056.1.
- chr22:18,846,811–18,861,049, 2 genes: AC008132.1, BCRP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 29 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,419,273, 4 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:90,102,271–90,178,344, 1 gene, copy number 6 (within-gene range 2–6): FAM157C.
- chr16:90,110,574–90,168,225, 2 genes, copy number 6: AC133919.2, RNU6-355P.
- chr16:90,174,062–90,175,865, 1 gene, copy number 6: CICP25.
- chr21:10,482,738–13,067,033, 9 genes, copy number 6–7 (within-gene range 3–7): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.
- chr22:18,636,445–18,653,617, 2 genes, copy number 20: CA15P2, PPP1R26P2.
- chr22:18,733,914–18,843,399, 3 genes, copy number 7–8 (within-gene range 1–8): FAM230E, GGT3P, AC008132.2.
- chr22:18,873,543–18,894,407, 2 genes, copy number 5 (within-gene range 5–9): FAM230F, AC008103.1.
- chr22:21,103,016–21,142,371, 4 genes, copy number 6–8: BCRP2, AP000550.1, POM121L7P, E2F6P2.
- chr22:42,835,412–43,015,149, 1 gene, copy number 6 (within-gene range 3–6): PACSIN2.

Autosomal genes at a single copy (total copy number 1): 8,674. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
